Somatic mutation profile of tumor specimen TCGA-D3-A2JC-06A (aliquot TCGA-D3-A2JC-06A-11D-A19A-08) from TCGA case TCGA-D3-A2JC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 53.8 years (19,644 days).
Specimen TCGA-D3-A2JC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5532ade-c244-4ffe-89bc-b5e4744f4576.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2JC-10A (Blood Derived Normal), aliquot TCGA-D3-A2JC-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcaeaf64-1d00-4991-af3b-ccb4a4c33f1a

The open-access MAF lists 221 somatic variants for this specimen: 144 protein-altering or splice-affecting, 74 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 74, Nonsense Mutation 9, Splice Site 3, RNA 2, Frame Shift Ins 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.2549C>T p.S850F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55963228; called by muse, mutect2, varscan2
- ABCC8 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 73/245 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1243040456, COSV56857592; called by muse, varscan2
- ABCC9 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1212315529, COSV53966264; called by mutect2, varscan2
- ACOX3 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs148322745; called by muse, mutect2, varscan2
- ACSBG2 | c.1063A>G p.K355E | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53127726; called by muse, mutect2, varscan2
- ADAMTS7 | c.1567C>T p.L523F | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66309372; called by muse, mutect2, varscan2
- ADH1B | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV59294987; called by muse, varscan2
- ALDOB | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs201424676, COSV66398632; called by muse, mutect2, varscan2
- AMER3 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as COSV58469940; called by muse, mutect2, varscan2
- ANKRD13C | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 90/144 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52028831; called by muse, mutect2, varscan2
- ART5 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as rs773506388, COSV63365419; called by mutect2, varscan2
- ASPM | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.212); catalogued as rs772696379, COSV54133066; called by muse, mutect2, varscan2
- ATL1 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as rs1159790126, COSV63297697; called by mutect2, varscan2
- ATP2C1 | c.2365G>T p.G789W | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM020638, COSV60762603; called by mutect2, varscan2
- BMP15 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV53141971; called by muse, varscan2
- BMX | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1467580394, COSV59593407; called by mutect2, varscan2
- C5orf49 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.662); catalogued as rs200521160, COSV57899572; called by muse, mutect2, varscan2
- CA10 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53362092; called by mutect2, varscan2
- CA9 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV65676501; called by mutect2, varscan2
- CA9 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as rs775063591, COSV65675129; called by muse, mutect2, varscan2
- CACNA1C | c.6217G>A p.G2073S (on ENST00000399634 / NM_001167625.1; = p.G2002S on NM_000719.7) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV59769075; called by muse, mutect2, varscan2
- CACNA1S | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.124); catalogued as COSV62943510; called by muse, mutect2, varscan2
- CARD10 | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52659953; called by muse, mutect2, varscan2
- CARD11 | c.2735G>A p.R912Q | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs368119340; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC88C | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1344423369, COSV66236896; called by mutect2, varscan2
- CDKL5 | c.2518C>T p.R840C | Missense Mutation (SNP) | VAF 98/297 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV66111770; called by mutect2, varscan2
- CEP126 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54825434, COSV99681070; called by muse, varscan2
- CEP135 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs149954755; called by muse, mutect2, varscan2
- CEP72 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV53796998; called by muse, mutect2, varscan2
- CFAP43 | c.2950A>G p.T984A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as COSV53381157; called by muse, varscan2
- CHEK2 | c.1709C>T p.A570V (on ENST00000382580 / NM_001005735.2; = p.A527V on NM_007194.4) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV60426164; called by muse, mutect2, varscan2
- CHRDL1 | c.895C>T p.R299* (on ENST00000372045; = p.R305* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | catalogued as COSV54323287; called by mutect2, varscan2
- CLCN5 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV56586747; called by muse, mutect2, varscan2
- CMYA5 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757381527, COSV71409396; called by muse, mutect2, varscan2
- CNGA2 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61703480; called by muse, mutect2, varscan2
- COBL | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV54358135; called by muse, mutect2, varscan2
- COL3A1 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV58596225; called by muse, mutect2, varscan2
- COL5A1 | c.1348G>A p.G450S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100880379, COSV100880548; called by muse, mutect2, varscan2
- COL5A1 | c.1349G>A p.G450D | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65674430; called by muse, mutect2, varscan2
- CR1 | c.2803C>T p.P935S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV65463066; called by muse, varscan2
- CRHBP | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs1407656696, COSV57189188; called by mutect2, varscan2
- CRISP2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV59256789; called by muse, mutect2, varscan2
- CSMD1 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.919); catalogued as COSV68205737; called by muse, mutect2, varscan2
- CYLC2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV66336737, COSV66337270; called by mutect2, varscan2
- DAGLA | c.2098C>T p.P700S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.05); catalogued as COSV57199569; called by muse, mutect2, varscan2
- DMXL2 | c.6531G>A p.M2177I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV51855917; called by muse, mutect2, varscan2
- DNAH5 | c.13724-1G>A p.X4575_splice | Splice Site (SNP) | VAF 25/46 reads (54%) | catalogued as COSV99452691; called by muse, mutect2, varscan2
- DNAH5 | c.13132G>A p.E4378K | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.292); catalogued as COSV54242655; called by muse, varscan2
- DNAH9 | c.13035G>A p.W4345* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV52376125; called by muse, mutect2, varscan2
- DOCK3 | c.2411C>T p.T804I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as COSV56549174; called by muse, mutect2, varscan2
- DSCAM | c.5270C>T p.P1757L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV68035857; called by muse, mutect2, varscan2
- DSCAML1 | c.4092G>A p.M1364I (on ENST00000321322; = p.M1304I on NM_020693.4) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV58392393; called by mutect2, varscan2
- ELN | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.49); catalogued as COSV52715364; called by muse, mutect2, varscan2
- FAM209A | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767948280, COSV54766034; called by mutect2, varscan2
- FANCD2 | c.3301G>A p.G1101R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV99812116; called by muse, mutect2, varscan2
- FAT3 | c.12943G>A p.G4315R | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.748); catalogued as COSV53172260; called by muse, varscan2
- FAT4 | c.13502C>T p.S4501F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.992); catalogued as COSV58678747; called by muse, mutect2, varscan2
- FBXO24 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV99575570; called by muse, mutect2, varscan2
- FCHO1 | c.1972A>G p.T658A | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV53185410; called by muse, mutect2
- FLT3 | c.1311G>A p.R437= | Splice Region (SNP) | VAF 25/51 reads (49%) | catalogued as COSV54054799; called by muse, mutect2, varscan2
- G6PD | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs202122673, COSV63704423; called by muse, mutect2, varscan2
- GBP6 | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as COSV100969627, COSV65010602; called by muse, mutect2, varscan2
- GEM | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs761960990, COSV52599103; called by mutect2, varscan2
- GLIPR1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99875828; called by muse, mutect2, varscan2
- GNL3L | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV60575533; called by mutect2, varscan2
- GRID1 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.043); catalogued as rs1291746299, COSV60052320; called by muse, mutect2, varscan2
- GRIN2A | c.4208C>T p.S1403L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.387); catalogued as COSV58030280; called by muse, mutect2, varscan2
- HELQ | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs765695614, COSV55027898, COSV55028013; called by muse, mutect2, varscan2
- HMCN1 | c.16576G>A p.E5526K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54940368; called by muse, mutect2, varscan2
- HNMT | c.723G>A p.W241* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as rs1299154570, COSV54505885; called by muse, mutect2, varscan2
- HUWE1 | c.6730A>G p.N2244D | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53363514; called by muse, mutect2, varscan2
- INVS | c.1234G>A p.G412S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV52449841; called by muse, mutect2, varscan2
- ITGB8 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.379); catalogued as COSV56014211; called by muse, mutect2, varscan2
- LARP1 | c.1978G>C p.D660H (on ENST00000518297 / NM_033551.3; = p.D583H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765076218, COSV100303679, COSV100304002, COSV60425194; called by muse, mutect2, varscan2
- LRRC37B | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.758); catalogued as COSV58954873; called by muse, mutect2, varscan2
- MAGEB6 | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV66873036; called by muse, varscan2
- MAPK8IP2 | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV50509419; called by muse, mutect2, varscan2
- MARCHF10 | c.2150G>A p.G717D | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV60890383; called by muse, mutect2, varscan2
- MPP4 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59632502; called by muse, varscan2
- MTMR12 | c.1727G>A p.R576K | Missense Mutation (SNP) | VAF 76/150 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV53782959, COSV53785170, COSV53787945; called by muse, varscan2
- MTMR12 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV53787953, COSV99373943; called by muse, mutect2, varscan2
- MUC16 | c.15569C>T p.P5190L | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs1207399715, COSV101200832; called by muse, mutect2, varscan2
- MUC16 | c.15568C>T p.P5190S | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.197); catalogued as rs1207619912, COSV101200833; called by muse, mutect2, varscan2
- MUC16 | c.5684C>T p.S1895F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV67482126; called by muse, mutect2, varscan2
- NAT2 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as COSV54063151; called by mutect2, varscan2
- NECAB1 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs1299554994, COSV70238009; called by mutect2, varscan2
- NLRP3 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs201678213, COSV60227238; called by mutect2, varscan2
- NLRP7 | c.1902G>A p.M634I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV60181673; called by muse, varscan2
- NOTCH4 | c.3479C>T p.S1160F | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV66683691; called by muse, mutect2, varscan2
- NR1H4 | c.719G>A p.G240D (on ENST00000551379 / NM_001206993.2; = p.G226D on NM_005123.4) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV51856756; called by mutect2, varscan2
- NR5A2 | c.323G>A p.G108E (on ENST00000367362 / NM_205860.3; = p.G62E on NM_003822.5) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52646891; called by muse, varscan2
- OR10A3 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62460223; called by muse, mutect2, varscan2
- OR1G1 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV61030202; called by muse, mutect2, varscan2
- OR6N1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV58648016; called by muse, mutect2, varscan2
- OR6V1 | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs753609317, COSV69237679; called by muse, mutect2, varscan2
- OTOGL | c.493C>T p.H165Y (on ENST00000547103; = p.H156Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV72006446; called by mutect2, varscan2
- OVCA2 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV53986507; called by muse, mutect2, varscan2
- PCCB | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.239); catalogued as COSV99291565; called by muse, mutect2
- PCDHA2 | c.1138G>A p.G380S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1554119701; called by muse, mutect2, varscan2
- PCDHA8 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV65336108, COSV65340396; called by muse, mutect2, varscan2
- PLIN4 | c.3050C>T p.S1017F (on ENST00000301286; = p.S1032F on NM_001367868.2) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV56698531; called by muse, mutect2, varscan2
- PLXNA4 | c.3688C>T p.P1230S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771687932, COSV58159355; called by muse, mutect2, varscan2
- PTPN22 | c.1613C>T p.S538L (on ENST00000359785 / NM_001193431.2; = p.S483L on NM_012411.5) | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs756859042, COSV63086569; called by muse, mutect2, varscan2
- PTPRB | c.3701C>T p.P1234L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1399293300, COSV99718585; called by muse, mutect2, varscan2
- RALGAPA1 | c.5978+2T>C p.X1993_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | catalogued as COSV51896296; called by muse, mutect2, varscan2
- RGP1 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV65240463; called by muse, mutect2, varscan2
- RNF38 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as rs149052036, COSV52397445; called by muse, varscan2
- RPE65 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV52018593; called by mutect2, varscan2
- RUNDC1 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV64512626; called by muse, mutect2, varscan2
- SAMD12 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV100126604; called by muse, mutect2, varscan2
- SAMD12 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV100126606; called by mutect2, varscan2
- SCN2A | c.1606G>A p.G536S | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.031); catalogued as rs767879275, COSV51854877; called by muse, mutect2, varscan2
- SFTPD | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64853724; called by mutect2, varscan2
- SH3KBP1 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65644574; called by muse, mutect2, varscan2
- SLC13A1 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52016796, COSV99520845; called by muse, varscan2
- SLC17A8 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60122700; called by muse, varscan2
- SMC4 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as rs368979205; called by mutect2, varscan2
- SNX31 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs765359363, COSV61261774; called by mutect2, varscan2
- SORL1 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs756987309, COSV52762398; called by muse, mutect2, varscan2
- SOX5 | c.626T>A p.L209Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58647950; called by muse, mutect2, varscan2
- SPAG17 | c.5135C>T p.P1712L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV60468195; called by muse, mutect2, varscan2
- SPAM1 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113752093, COSV56142892; called by mutect2, varscan2
- SPEF2 | c.5197G>A p.E1733K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.068); catalogued as COSV57430935; called by mutect2, varscan2
- SPON1 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs367855100; called by muse, mutect2, varscan2
- SYT9 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs765568180, COSV59624431; called by mutect2, varscan2
- TCTN2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766012866, COSV57632562; called by muse, varscan2
- TDRD9 | c.3019C>T p.Q1007* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV59155860; called by muse, mutect2, varscan2
- TFAP2C | c.8G>A p.W3* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99571673; called by muse, varscan2
- TGS1 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV52702275; called by mutect2, varscan2
- TIE1 | c.2714G>A p.G905E | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65251348; called by muse, mutect2, varscan2
- TLR4 | c.2201T>C p.I734T (on ENST00000355622 / NM_138554.5; = p.I694T on NM_003266.4) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62924202; called by muse, mutect2, varscan2
- TNFRSF17 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV50001880; called by muse, mutect2, varscan2
- TPH1 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV51460469; called by muse, mutect2, varscan2
- TTC24 | c.943A>T p.S315C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV63998468; called by mutect2, varscan2
- UBN1 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as rs890303868, COSV52172760; called by muse, mutect2, varscan2
- UNC5D | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV54782058; called by muse, mutect2, varscan2
- WWC3 | c.2920C>T p.Q974* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV66507308; called by muse, mutect2, varscan2
- ZIC2 | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV66255499; called by muse, mutect2, varscan2
- ZNF205 | c.1062C>G p.H354Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54622882; called by muse, mutect2, varscan2
- ZNF808 | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.763); catalogued as COSV63121687; called by muse, mutect2, varscan2
- ZSWIM1 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 35/68 reads (51%) | catalogued as rs1024173669, COSV54851414; called by muse, mutect2, varscan2
- CASP8 | c.411+2dup p.X137_splice (on ENST00000432109 / NM_033355.3; = p.X169_splice on NM_001228.4) | Splice Site (INS) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- FCGBP | c.5440C>T p.L1814F | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- PTEN | c.270_271insTTTTTTTT p.E91Ffs*11 | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | called by mutect2*, pindel, varscan2*
- ADAMTS15 | c.1680G>A p.V560= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs779335515, COSV54509661; called by mutect2, varscan2
- ADCY4 | c.1191C>T p.N397= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV60257569; called by muse, mutect2, varscan2
- ADGRB1 | c.2499G>A p.R833= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV60103362; called by mutect2, varscan2
- ADH1A | c.876C>T p.I292= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs1262171039, COSV52924492; called by mutect2, varscan2
- AKAP6 | c.1104C>T p.T368= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs749350907, COSV55232835; called by muse, mutect2, varscan2
- ARF3 | c.138C>T p.I46= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV56741861; called by muse, mutect2, varscan2
- ATXN7L2 | c.663G>A p.G221= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as COSV63992935; called by muse, mutect2, varscan2
- BPIFB2 | c.1131G>A p.G377= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs761624498, COSV50067992, COSV50070604; called by muse, mutect2, varscan2
- CACNA1E | c.1149C>T p.Y383= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV62420197; called by muse, mutect2, varscan2
- CCDC87 | c.651C>T p.F217= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs17853294, COSV59578208; called by mutect2, varscan2
- CCPG1 | c.1602A>G p.R534= | Silent (SNP) | VAF 38/131 reads (29%) | catalogued as COSV51244015; called by muse, mutect2, varscan2
- CD163 | c.471G>A p.L157= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs1344013682, COSV63137004; called by muse, mutect2, varscan2
- CDH4 | c.462G>A p.P154= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs1367281800, COSV64649730; called by mutect2, varscan2
- CFAP54 | c.4803G>A p.K1601= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV61571792; called by muse, mutect2, varscan2
- CIITA | c.3105C>T p.L1035= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as rs1297513528, COSV60854055; called by mutect2, varscan2
- CPED1 | c.2314C>T p.L772= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV60012901; called by muse, mutect2, varscan2
- CRYGB | c.42C>T p.G14= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV53680856; called by muse, mutect2, varscan2
- CTSA | c.213G>A p.K71= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV51944856; called by muse, mutect2, varscan2
- DDX20 | c.1749C>A p.I583= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs1233470809, COSV63782000; called by mutect2, varscan2
- DEAF1 | c.543G>A p.L181= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV58609281; called by mutect2, varscan2
- DECR1 | c.129C>T p.F43= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV55166456, COSV55167083, COSV55170605; called by muse, mutect2, varscan2
- DGKZ | c.1140C>T p.F380= (on ENST00000454345 / NM_001105540.2; = p.F192= on NM_003646.4) | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV58994894; called by muse, mutect2, varscan2
- DYRK2 | c.1164C>T p.Y388= (on ENST00000344096 / NM_006482.3; = p.Y315= on NM_003583.4) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV59847460; called by muse, mutect2, varscan2
- EPHA7 | c.534C>T p.S178= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100992479; called by muse, mutect2, varscan2
- EPX | c.828G>A p.K276= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV56599188; called by muse, mutect2, varscan2
- FAM83C | c.1425G>A p.E475= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV100981648; called by muse, mutect2, varscan2
- FATE1 | c.330C>T p.F110= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1390710129, COSV64848907; called by muse, mutect2, varscan2
- GALNT15 | c.102C>T p.H34= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs376820795, COSV60219795; called by muse, mutect2, varscan2
- GLIPR1 | c.195C>T p.A65= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV99875831; called by muse, mutect2, varscan2
- GPR141 | c.120C>T p.F40= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs770073216, COSV57734010; called by muse, mutect2, varscan2
- HIPK4 | c.477C>T p.F159= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs745473915, COSV52519032; called by mutect2, varscan2
- IGLV3-1 | c.282C>T p.S94= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs547382671; called by mutect2, varscan2
- KRT32 | c.843G>A p.R281= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV56785641, COSV56788097; called by muse, mutect2, varscan2
- LARP1 | c.1977G>A p.G659= (on ENST00000518297 / NM_033551.3; = p.G582= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100304000; called by muse, mutect2, varscan2
- LEPR | c.2220C>T p.I740= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs757501135, COSV60750793; called by mutect2, varscan2
- LILRA4 | c.303G>A p.Q101= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV52490142, COSV52494686; called by muse, mutect2, varscan2
- LRIT2 | c.699C>T p.G233= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV60566357; called by muse, varscan2
- LRRN1 | c.795G>A p.L265= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100076193, COSV60016179; called by mutect2, varscan2
- LYN | c.1284C>T p.S428= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV70206403; called by muse, mutect2, varscan2
- MMP16 | c.576C>T p.F192= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV54167008; called by mutect2, varscan2
- MTREX | c.2379C>T p.V793= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV57930083; called by mutect2, varscan2
- NCAPD3 | c.2982C>T p.I994= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV73244869; called by mutect2, varscan2
- NEU2 | c.951C>T p.A317= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV52094025, COSV99290540; called by muse, varscan2
- OR2G6 | c.198C>T p.L66= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV58575836; called by muse, mutect2, varscan2
- OR4N5 | c.225C>T p.F75= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV61320255, COSV61321139; called by mutect2, varscan2
- OR7D4 | c.139C>T p.L47= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV58071069, COSV58071496, COSV58072540; called by muse, mutect2, varscan2
- PHF14 | c.2802T>C p.N934= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV71003060; called by muse, mutect2, varscan2
- PIK3AP1 | c.330G>A p.E110= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as COSV59537252; called by muse, mutect2, varscan2
- PKNOX2 | c.882C>T p.V294= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV53554551; called by muse, mutect2, varscan2
- PLBD2 | c.1743C>T p.F581= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs749081232, COSV55108990; called by mutect2, varscan2
- PLSCR2 | c.792C>T p.N264= (on ENST00000497985 / NM_001199978.1; = p.N191= on NM_020359.2) | Silent (SNP) | VAF 46/87 reads (53%) | catalogued as COSV60864739; called by muse, mutect2, varscan2
- PNPLA3 | c.1296C>T p.S432= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as rs1426390249, COSV53379074, COSV53380433; called by muse, mutect2, varscan2
- PRAMEF4 | c.114C>T p.F38= | Silent (SNP) | VAF 37/71 reads (52%) | catalogued as rs775270846, COSV52439205; called by muse, mutect2, varscan2
- PTPRT | c.1974C>T p.L658= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs374933401, COSV61967650; called by muse, mutect2, varscan2
- RIMS2 | c.2916T>G p.T972= (on ENST00000666250 / NM_001348490.2; = p.T780= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV51722893; called by muse, mutect2, varscan2
- SI | c.12G>A p.K4= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs370524643, COSV52281419; called by muse, mutect2, varscan2
- SLC12A1 | c.1419A>G p.E473= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV66799641; called by muse, mutect2, varscan2
- SLC12A6 | c.1296C>T p.I432= (on ENST00000354181 / NM_001365088.1; = p.I381= on NM_005135.2) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV51631751; called by muse, mutect2, varscan2
- SLC15A2 | c.213C>T p.F71= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs200627431, COSV55199645; called by muse, mutect2, varscan2
- SLC22A12 | c.63G>A p.T21= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs762500419, COSV60571136; called by mutect2, varscan2
- SLC25A2 | c.624C>T p.G208= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV53405009; called by muse, mutect2, varscan2
- SLITRK3 | c.2733G>A p.K911= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV53853270, COSV99578745; called by muse, mutect2, varscan2
- SPANXN2 | c.117G>A p.Q39= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV65129427; called by muse, mutect2, varscan2
- SYPL2 | c.282C>T p.P94= | Silent (SNP) | VAF 48/174 reads (28%) | catalogued as rs779994779, COSV63995351; called by muse, mutect2, varscan2
- TNS2 | c.1432C>T p.L478= (on ENST00000314250 / NM_170754.4; = p.L488= on NM_015319.2) | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV58581946; called by muse, mutect2, varscan2
- TRIM29 | c.1401C>T p.T467= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV59282152; called by muse, mutect2, varscan2
- TRPM5 | c.3153C>T p.V1051= | Silent (SNP) | VAF 42/164 reads (26%) | catalogued as rs762301888, COSV50192931; called by mutect2, varscan2
- TTC16 | c.1650G>A p.A550= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs762198036, COSV60162103; called by mutect2, varscan2
- VAX1 | c.408G>A p.Q136= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs527889359, COSV53330772; called by muse, mutect2, varscan2
- VSTM2A | c.153G>A p.Q51= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV56496573; called by muse, mutect2, varscan2
- VTI1A | c.177C>T p.V59= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs566700471, COSV67583882; called by muse, mutect2, varscan2
- ZHX1 | c.63C>T p.D21= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV52879007; called by muse, varscan2
- ZNF670 | c.618C>T p.F206= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV63608993; called by mutect2, varscan2
- ZNF711 | c.387C>T p.F129= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs867259256, COSV52156636; called by muse, varscan2
- AP000769.5 | chr11:65498635 T>C | 5'Flank (SNP) | VAF 9/39 reads (23%) | catalogued as rs374052013; called by muse, mutect2, varscan2
- MIR487B | n.54C>T | RNA (SNP) | VAF 8/40 reads (20%) | catalogued as rs1402013521; called by mutect2, varscan2
- MIR891B | n.15A>G | RNA (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
